Somatic mutation profile of cancer-model specimen HCM-BROD-0613-C71-85A (Adherent Cell Line, passage 10; aliquot HCM-BROD-0613-C71-85A-01D-A80U-36), derived from the primary tumor of HCMI case HCM-BROD-0613-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.0 years (18,640 days).
Specimen HCM-BROD-0613-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa42c533-0860-4f07-9bb1-a7d65680193f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0613-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0613-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86ed5527-4db7-4c5d-8d8d-1efb362eea0e

The open-access MAF lists 49 somatic variants for this specimen: 32 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 14, Splice Region 2, Frame Shift Del 2, Intron 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 288/448 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKMY1 | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 134/259 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775170853; called by muse, mutect2, varscan2
- ANKRD33 | c.428G>A p.G143E (on ENST00000340970 / NM_001304459.2; = p.G268E on NM_182608.4) | Missense Mutation (SNP) | VAF 344/692 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.054); catalogued as COSV56608802; called by muse, mutect2
- APEX2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.676); catalogued as rs763356429, COSV66624147; called by muse, mutect2
- BTBD16 | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 117/117 reads (100%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs577596137; called by muse, mutect2, varscan2
- COL6A6 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 198/569 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as rs747310047, COSV100650672; called by muse, mutect2, varscan2
- CRACD | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 183/386 reads (47%) | catalogued as rs777119246, COSV51726266; called by muse, mutect2, varscan2
- DNAH3 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs528418539, COSV54544211; called by muse, mutect2, varscan2
- DNAJB9 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 138/585 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99974410; called by muse, mutect2, varscan2
- EIF4G3 | c.3509G>A p.R1170Q | Missense Mutation (SNP) | VAF 166/376 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as rs541460610; called by muse, mutect2, varscan2
- MARCHF10 | c.1187C>G p.A396G | Missense Mutation (SNP) | VAF 167/335 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as rs376963369; called by muse, mutect2, varscan2
- MARCHF3 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 19/398 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV58036708; called by muse, mutect2
- MYOM3 | c.3621C>T p.D1207= | Splice Region (SNP) | VAF 111/238 reads (47%) | catalogued as rs372739261; called by muse, mutect2, varscan2
- OR1J2 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 236/491 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.773); catalogued as rs201746798; called by muse, mutect2, varscan2
- PCDHGC4 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 183/370 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs372373315; called by muse, mutect2, varscan2
- PCNX1 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 155/345 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as COSV53090425; called by muse, mutect2, varscan2
- SLC23A3 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 149/266 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as rs192655015; called by muse, mutect2, varscan2
- SMG1 | c.2181G>T p.T727= | Splice Region (SNP) | VAF 52/112 reads (46%) | catalogued as COSV67171062; called by muse, mutect2, varscan2
- SYNE2 | c.14972T>G p.F4991C | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs943666082; called by muse, mutect2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 394/548 reads (72%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- CNIH4 | c.75del p.T26Hfs*5 | Frame Shift Del (DEL) | VAF 68/146 reads (47%) | called by mutect2, pindel*, varscan2
- GNAZ | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 157/319 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- GTPBP3 | c.1450A>G p.I484V | Missense Mutation (SNP) | VAF 89/337 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MSH4 | c.2779A>G p.T927A | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- NACAD | c.1754T>C p.I585T | Missense Mutation (SNP) | VAF 170/784 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.021); called by muse, varscan2
- NHS | c.2569G>A p.G857S | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPY1R | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 154/309 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PRKCG | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 189/385 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- RGPD3 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC26A1 | c.930G>C p.Q310H | Missense Mutation (SNP) | VAF 263/490 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZBTB7A | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 270/517 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF254 | c.1399T>C p.C467R | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.16338G>A p.R5446= | Silent (SNP) | VAF 211/826 reads (26%) | called by muse, mutect2, varscan2
- CABLES2 | c.1293C>T p.I431= | Silent (SNP) | VAF 128/270 reads (47%) | catalogued as rs200996959; called by muse, mutect2
- CCDC88C | c.2136G>A p.L712= | Silent (SNP) | VAF 152/373 reads (41%) | called by muse, mutect2, varscan2
- CLEC1B | c.498G>A p.S166= | Silent (SNP) | VAF 228/329 reads (69%) | catalogued as rs370262331; called by muse, mutect2, varscan2
- CRH | c.444G>A p.P148= | Silent (SNP) | VAF 201/629 reads (32%) | catalogued as rs202050760; called by muse, mutect2, varscan2
- H4C8 | c.126C>T p.G42= | Silent (SNP) | VAF 374/375 reads (100%) | catalogued as rs144152120; called by muse, mutect2, varscan2
- MCU | c.603G>A p.R201= | Silent (SNP) | VAF 279/279 reads (100%) | called by muse, mutect2, varscan2
- MGAM2 | c.612G>A p.Q204= | Silent (SNP) | VAF 161/674 reads (24%) | catalogued as rs1396281184; called by muse, mutect2, varscan2
- MMRN1 | c.1704C>T p.H568= | Silent (SNP) | VAF 119/237 reads (50%) | catalogued as rs781201120; called by muse, mutect2, varscan2
- OLFML2B | c.2031C>T p.F677= | Silent (SNP) | VAF 118/258 reads (46%) | catalogued as rs1346925350, COSV54194943; called by muse, mutect2, varscan2
- OR5BS1P | c.9C>A p.V3= | Silent (SNP) | VAF 291/517 reads (56%) | called by muse, mutect2, varscan2
- OSBP | c.906C>A p.I302= | Silent (SNP) | VAF 149/635 reads (23%) | called by muse, mutect2, varscan2
- SALL4 | c.591C>T p.S197= | Silent (SNP) | VAF 160/382 reads (42%) | catalogued as rs764301551; called by muse, mutect2, varscan2
- SLCO6A1 | c.63G>A p.P21= | Silent (SNP) | VAF 223/440 reads (51%) | catalogued as rs762072743, COSV65812043; called by muse, mutect2, varscan2
- DCHS2 | n.6657A>C | RNA (SNP) | VAF 207/380 reads (54%) | called by muse, mutect2, varscan2
- MAST4 | c.675-67929C>A | Intron (SNP) | VAF 163/292 reads (56%) | called by muse, mutect2, varscan2
- SCN1B | c.448+225C>T | Intron (SNP) | VAF 229/474 reads (48%) | catalogued as rs369588692; ClinVar: uncertain significance; called by muse, mutect2
